Somatic mutation profile of tumor specimen C3L-02956-01 (aliquot CPT0161630032) from CPTAC case C3L-02956, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 84.1 years (30,711 days).
Specimen C3L-02956-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e89a8d98-7435-4b20-a905-a3654a9f5154.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-02956-31 (Blood Derived Normal), aliquot CPT0162530002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b6e1e0cb-90f7-44d5-a359-98004c5f0f35

The open-access MAF lists 21 somatic variants for this specimen: 11 protein-altering or splice-affecting, 7 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Silent 7, Intron 2, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 50/538 reads (9%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- HEPH | c.3418C>G p.R1140G (on ENST00000343002; = p.R873G on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/564 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.993); catalogued as COSV57966393; called by muse, mutect2
- PCDH11X | c.2431G>T p.V811F | Missense Mutation (SNP) | VAF 26/768 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV53457151; called by muse, mutect2
- SNX12 | c.116C>T p.T39M | Missense Mutation (SNP) | VAF 11/270 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as COSV52145947; called by muse, mutect2
- C4orf54 | c.3931A>G p.K1311E | Missense Mutation (SNP) | VAF 23/345 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.031); called by muse, mutect2
- CHM | c.1489A>T p.M497L | Missense Mutation (SNP) | VAF 22/576 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.197); called by muse, mutect2
- FJX1 | c.1070A>G p.N357S | Missense Mutation (SNP) | VAF 82/1182 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.649); called by muse, mutect2
- FRY | c.7012C>G p.P2338A | Missense Mutation (SNP) | VAF 19/646 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SLC25A46 | c.931G>C p.D311H | Missense Mutation (SNP) | VAF 14/354 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, mutect2
- TAF3 | c.532A>G p.K178E | Missense Mutation (SNP) | VAF 12/297 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.696); called by muse, mutect2
- ZNF536 | c.878T>C p.I293T | Missense Mutation (SNP) | VAF 30/466 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- DEAF1 | c.1674C>T p.S558= | Silent (SNP) | VAF 61/912 reads (7%) | catalogued as rs766292709; called by muse, mutect2
- FAM78A | c.441C>T p.P147= | Silent (SNP) | VAF 16/340 reads (5%) | catalogued as rs768427039; called by muse, mutect2
- FAT3 | c.11163G>A p.K3721= | Silent (SNP) | VAF 11/223 reads (5%) | catalogued as COSV53159552; called by muse, mutect2
- HPR | c.60G>A p.L20= | Silent (SNP) | VAF 25/566 reads (4%) | catalogued as rs767678228; called by muse, mutect2
- KIR2DS4 | c.483C>T p.N161= | Silent (SNP) | VAF 18/734 reads (2%) | catalogued as rs761946010; called by muse, mutect2
- NAP1L3 | c.288C>T p.F96= | Silent (SNP) | VAF 20/428 reads (5%) | catalogued as COSV100220657; called by muse, mutect2
- NR2F1 | c.792G>A p.A264= | Silent (SNP) | VAF 29/705 reads (4%) | called by muse, mutect2
- CTCFL | c.1674+1023A>T | Intron (SNP) | VAF 26/441 reads (6%) | catalogued as rs1344354161; called by muse, mutect2
- DDX3X | c.104-11T>A | Intron (SNP) | VAF 8/164 reads (5%) | catalogued as rs980049998, COSV67864083; called by muse, mutect2
- MFSD5 | chr12:53251834 G>A | 5'Flank (SNP) | VAF 23/568 reads (4%) | called by muse, mutect2
